Surgical pathology report (de-identified scan), TCGA case TCGA-TS-A8AV, project TCGA-MESO (Mesothelioma), tissue source site University of Pennsylvania, specimen TCGA-TS-A8AV-01A (Primary Tumor).

[page 1 of 4]
Print Date:

Date Collected:

Date Received:

Accession

Physician:

Copy to:

years Sex: Male

Surgical Pathology Report

Accession Number	Collection Date/Time	Received Date/Time	Verified Date/Time	Pathologist
------------------	----------------------	--------------------	--------------------	-------------

Clinical Information

year old male with mesothelioma; Thoracotomy, Right PDT, Bronchoscopy, Radical Pleurectomy

ICD-O-3

Final Diagnosis

1. SKIN, PREVIOUS INCISIONAL AREA, EXCISION:
Representative section of skin showing dermal fibrosis.
No evidence of residual tumor.

Mesothelioma, sarcomatoid 9051/3
Site: Pleura NOS C38.4
JW 5/28/14

2. RIB:
Benign cancellous bone containing unremarkable bone marrow elements.
Adherent benign fibroadipose tissue and striated muscle.

3. LEVEL 4:
Four of multiple fragments of lymph node, positive for metastatic malignant mesothelioma.

4. LEVEL 9:
Fibroadipose showing nodular foci of sarcomatoid malignant mesothelioma with focal areas of necrosis.
Scant compressed lymphoid tissue noted at the peripheral of nodules.
Scant benign adherent lung parenchyma also present.

5. LEVEL 10:
One lymph node, positive for metastatic malignant mesothelioma.

6. LEVEL 2:
One lymph node, positive for metastatic malignant mesothelioma.
Other fragment of tissue containing scant lung parenchyma showing nodular malignant mesothelioma.

7. PLEURA:
Malignant mesothelioma, sarcomatoid type with areas of necrosis.
Tumor invades the adjacent lung parenchyma.

8. LUNG, WEDGE RESECTION:
Benign alveolar lung parenchyma.

9. LUNG IMPLANT:
Malignant mesothelioma, sarcomatoid type.

10. LEVEL 7:

Name
MRN

[page 2 of 4]
Print Date:
Date Collected:
Date Received:
Accession No. [REDACTED]
Physician:
Copy to:

[REDACTED] Age: [REDACTED] years Sex: Male

S u r g i c a l P a t h o l o g y R e p o r t

Accession Number	Collection Date/Time	Received Date/Time	Verified Date/Time	Pathologist
------------------	----------------------	--------------------	--------------------	-------------

One of many lymph nodes, positive for metastatic malignant mesothelioma.

11. PLEURAL PLAQUE:

Hyalinized pleural tissue with presence of malignant mesothelioma, sarcomatoid type.

12. POSTERIOR INTERCOSTAL:

One of two lymph nodes, positive for metastatic malignant mesothelioma.

13. POST TREATMENT DIAPHRAGM:

Benign fibroadipose tissue with acute inflammation.
Negative for malignancy.

The case material was reviewed and the report verified by:
(Electronic signature)
Verification Date:

Note

Immunostains with adequate controls performed on three blocks reveal tumor cells are diffusely and strongly positive for Cam5.2 and AE1-3. Tumor cells are focally positive for D2-40, calretinin, WT-1 and thrombomodulin. Tumor cells are negative for TTF-1, Mic-2, Bcl-2 and desmin.

See disclaimer:

Disclaimer:

The above in-vitro IHC tests may have used reagents labeled for IVD (In Vitro Diagnostic Use), IUO (Investigational Use Only) and/or RUO (Research Use Only) and have not been cleared or approved by the U.S Food and Drug Administration. However, the FDA has determined that such clearance or approval is not necessary for ASR class I tests intended to provide pathologists with adjunctive information to assist their morphologic evaluation. The tests using IUO or IUO reagents were developed and their performance characteristics were validated for diagnostic use by the

This laboratory is regulated under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical tests. These Class I ASR tests are not intended to provide diagnostic, prognostic, predictive or therapeutic information that is not directly confirmed by routine histopathologic internal or external control specimens.

Frozen Section Diagnosis

FS1: Multiple representative sections (6) fragments submitted. No evidence of tumor.

Name [REDACTED]
MRN [REDACTED]

[page 3 of 4]
Print Date:

Date Collected:

Date Received:

Accession N

Physician:

Copy to:

years Sex: Male

Surgical Pathology Report

Accession Number	Collection Date/Time	Received Date/Time	Verified Date/Time	Pathologist
------------------	----------------------	--------------------	--------------------	-------------

FS2A, FS2B: Malignant tumor present suggestive of sarcomatoid portion of malignant mesothelioma.

Gross Description

The specimen is received in 13 parts in a container labeled with the patient's name and medical record number.

Specimen #1 is designated "Previous Incision" and consists of an elongated fragment of skin with the surgical tape applied on the surface measuring 15.0 cm x 0.8 cm x 1.5 cm. There is an incisional scar present on the surface of the skin measuring 10.0 cm in length. Multiple representative sections are submitted in three cassettes from the frozen section.

Specimen #2 is designated "Rib" and consists of a portion of rib measuring 1.5 x 1.5 x 0.5 cm. Representative sections are submitted in one cassette.

Specimen #3 is designated "Level 4" and consists of multiple fragments of yellow-tan adipose tissue measuring in aggregate 3.0 x 2.0 x 0.5 cm. Within the adipose tissue, at least eight lymph nodes are identified measuring from 0.2 up to 1.2 cm in greatest dimension. The entire specimen is submitted in two cassettes.

Specimen #4 is designated "Level 9" and consists of three pink-tan ovoid firm tissue measuring 1.0, 1.5 and 2.5 cm in greatest dimension respectively. The specimen is bisected and submitted in three cassettes.

Specimen #5 is designated "Level 10" and consists of a single pink to yellow-tan ovoid soft tissue measuring 1.0 cm in greatest dimension. The specimen is bisected and submitted entirely in one cassette.

Specimen #6 is designated "Level 2" and consists of two pink-tan ovoid soft tissue measuring 0.9 cm in greatest dimension respectively. The entire specimen is submitted in one cassette.

Specimen #7 is designated "Pleura" and consists of multiple fragments of pink-tan to yellow-tan soft tissue consistent with pleura measuring in aggregate 35.0 cm x 15.0 cm x 6.0 cm. The soft tissue shows multiple pink-tan tumor nodules measuring from 0.2 up to 5.0 cm in greatest dimension. Representative sections are submitted in five cassettes.

Specimen #8 is designated "Lung" and consists of a single brown, spongy, unoriented, unstapled lung parenchyma measuring 1.5 x 1.5 x 1.0 cm. The specimen is serially sectioned and submitted entirely in two cassettes.

Specimen #9 is designated "Lung Implant" and consists of a single black-tan soft tissue measuring 0.3 cm. The entire specimen is submitted in one cassette.

Name
MRN

[page 4 of 4]
Print Date:

Date Collected:

Date Received:

Accession No. [REDACTED]

Physician:

Copy to:

[REDACTED] age: years Sex: Male

Surgical Pathology Report

Accession Number [REDACTED] Collection Date/Time Received Date/Time Verified Date/Time Pathologist

Specimen #10 is designated "Level 7" and consists of three black to pink-tan rounded lymph node-like soft tissue measuring from 0.2 up to 1.5 cm in greatest dimension. Also submitted in the same container is a yellow-tan to black irregular shaped soft tissue measuring 1.2 cm in greatest dimension. The entire specimen is submitted in two cassettes.

10A From the largest lymph node
10B Soft tissue and possible small lymph nodes

Specimen #11 is received fresh for frozen section and designated "Pleural Plaque" and consists of a single fragment of pink-tan membranous soft tissue measuring 5.0 x 3.0 cm in surface dimension and 0.2 up to 0.3 cm in thickness. The most thickened area was formed by nodular lesion and this area measures 1.0 cm in greatest dimension. Representative sections are submitted in two cassettes from the frozen section.

Specimen #12 is designated "Posterior Intercostal" and consists of two lymph nodes measuring 0.5 and 0.8 cm in greatest dimension, respectively. The entire specimen is submitted in one cassette.

Specimen #13 is designated "Post Treatment Diaphragm" and consists of four pieces of pink-tan to yellow-tan irregular shaped soft tissue measuring in aggregate 2.5 x 2.0 x 0.3 cm. The entire specimen is submitted in one cassette.

Dictated by:

Dictated by:

Pathologist(s)

Criteria	11/15/13	Yes	No
IIP/IA Discrepancy			✓

Name: [REDACTED]
MRN: [REDACTED]

Source: NCI Genomic Data Commons file 76fe0d62-4638-4583-a88d-3941bc9a2159 (TCGA-TS-A8AV.63E2F152-246D-43A2-8E02-D8F69FFBFBEF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).